Somatic mutation profile of tumor specimen MP2PRT-PAWCIU-TMP1-A (aliquot MP2PRT-PAWCIU-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAWCIU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,445 days).
Specimen MP2PRT-PAWCIU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a392c9a1-dade-4e1e-8b80-8c793e9bfe42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWCIU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWCIU-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7aae2a5-3abf-452a-9c0c-8bf4a6deb34c

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1736T>C p.V579A | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1057520022, COSV54065509, COSV54077224; ClinVar: likely pathogenic; called by muse, mutect2
- COL6A1 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 56/520 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs145838277; called by muse, mutect2, varscan2
- EML5 | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 69/345 reads (20%) | catalogued as rs1207811431; called by muse, mutect2, varscan2
- EPB41L4B | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 51/283 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs375528062; called by muse, mutect2, varscan2
- GJA4 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 62/428 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs771803516; called by muse, mutect2, varscan2
- GTF3C1 | c.3046C>T p.R1016C | Missense Mutation (SNP) | VAF 86/340 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs201589061; called by muse, mutect2, varscan2
- MAP2 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 138/362 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as rs147043359, COSV99558602; called by muse, mutect2, varscan2
- MECOM | c.2194C>T p.R732C (on ENST00000468789 / NM_001105078.4; = p.R920C on NM_004991.4) | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs763450489, COSV99245859; called by muse, mutect2, varscan2
- PLXNA4 | c.5363G>A p.R1788Q | Missense Mutation (SNP) | VAF 113/421 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as rs779684650, COSV58135981; called by muse, mutect2, varscan2
- SHB | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs746505733, COSV66629781; called by muse, mutect2, varscan2
- TP53BP2 | c.703G>A p.V235I (on ENST00000343537 / NM_001031685.3; = p.V106I on NM_005426.2) | Missense Mutation (SNP) | VAF 198/389 reads (51%) | SIFT tolerated (0.46); PolyPhen benign (0.263); catalogued as rs761975580; called by muse, mutect2, varscan2
- ANK3 | c.4405T>G p.Y1469D (on ENST00000280772 / NM_001320874.2; = p.Y594D on NM_001149.3) | Missense Mutation (SNP) | VAF 49/340 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- INSRR | c.2252T>A p.L751H | Missense Mutation (SNP) | VAF 66/788 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.299); called by muse, mutect2
- PIEZO1 | c.3457T>A p.S1153T | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- ABCC3 | c.1584G>A p.A528= | Silent (SNP) | VAF 26/754 reads (3%) | catalogued as rs1490949483, COSV99558672; called by muse, mutect2
- NLRP2 | c.1620C>T p.S540= | Silent (SNP) | VAF 71/369 reads (19%) | catalogued as rs190374903; called by muse, mutect2, varscan2
- PGR | c.636G>A p.P212= | Silent (SNP) | VAF 152/563 reads (27%) | called by muse, mutect2, varscan2
- CLEC20A | c.928+1778G>T | Intron (SNP) | VAF 251/628 reads (40%) | called by muse, mutect2, varscan2
- SCRN1 | c.342-3120C>T | Intron (SNP) | VAF 22/382 reads (6%) | catalogued as rs762755091; called by muse, mutect2
